Somatic mutation profile of tumor specimen TARGET-30-PARASL-01A (aliquot TARGET-30-PARASL-01A-01D) from TARGET case TARGET-30-PARASL, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 4.4 years (1,606 days).
Specimen TARGET-30-PARASL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3eecf045-f75a-4dda-bcdc-9bf0daa986e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARASL-10A (Blood Derived Normal), aliquot TARGET-30-PARASL-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4be1fcf-e6fb-4c88-a451-499043c3e381

The open-access MAF lists 28 somatic variants for this specimen: 23 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 4, Nonsense Mutation 1, Frame Shift Del 1, RNA 1, Splice Site 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADPRS | c.679C>A p.Q227K | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52881165; called by muse, mutect2, varscan2
- ARR3 | c.55G>T p.G19W | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57204303; called by muse, mutect2, varscan2
- C8orf37 | c.19G>C p.E7Q | Missense Mutation (SNP) | VAF 34/506 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV99713072; called by muse, mutect2
- CD1C | c.865G>T p.G289C | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63806662; called by muse, mutect2, varscan2
- DAXX | c.1927C>T p.P643S | Missense Mutation (SNP) | VAF 71/292 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV56470187, COSV56471515; called by muse, mutect2, varscan2
- DNAH17 | c.11434_11436del p.E3812del | In Frame Del (DEL) | VAF 6/71 reads (8%) | catalogued as rs1568059542; called by mutect2, pindel
- FOSL2 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1286334066, COSV53104255; called by muse, mutect2, varscan2
- FOXRED1 | c.170G>C p.S57T | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT tolerated (0.29); PolyPhen benign (0.055); catalogued as COSV55007124; called by muse, mutect2, varscan2
- KAT14 | c.857C>A p.T286K | Missense Mutation (SNP) | VAF 50/197 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as COSV66608014; called by muse, varscan2
- KMT2D | c.16513G>A p.G5505R | Missense Mutation (SNP) | VAF 63/277 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56449869; called by muse, mutect2, varscan2
- KRBA1 | c.2197del p.V733Lfs*99 | Frame Shift Del (DEL) | VAF 5/52 reads (10%) | catalogued as COSV55440644; called by mutect2, pindel
- LUM | c.115C>G p.P39A | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.636); catalogued as COSV57128402; called by muse, mutect2, varscan2
- MIER3 | c.1013G>T p.R338I (on ENST00000381199 / NM_001297599.2; = p.R337I on NM_152622.4) | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as COSV101167565, COSV67083178; called by muse, mutect2
- NIT1 | c.408G>A p.W136* | Nonsense Mutation (SNP) | VAF 33/72 reads (46%) | catalogued as COSV63501868; called by muse, mutect2, varscan2
- OR1L1 | c.332T>C p.F111S (on ENST00000373686; = p.F61S on NM_001005236.3) | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV58935786; called by muse, mutect2, varscan2
- PTK2 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.483); catalogued as COSV61786949; called by muse, mutect2, varscan2
- RTN4RL2 | c.119C>G p.S40C | Missense Mutation (SNP) | VAF 32/194 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV58652235; called by muse, mutect2, varscan2
- S100G | c.220G>A p.V74I | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV63722891; called by muse, mutect2, varscan2
- SLC13A1 | c.945G>A p.M315I | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.338); catalogued as rs1211686083, COSV52012731; called by muse, mutect2
- TNS3 | c.3011T>A p.L1004Q | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.216); catalogued as COSV60792508; called by muse, mutect2, varscan2
- ABCA6 | c.3295-1G>A p.X1099_splice | Splice Site (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- TRAJ33 | c.23T>C p.I8T | Missense Mutation (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- UNK | c.287_291dup p.G98Lfs*84 | Frame Shift Ins (INS) | VAF 26/167 reads (16%) | called by mutect2, pindel, varscan2
- CD163 | c.1035T>C p.C345= | Silent (SNP) | VAF 27/116 reads (23%) | catalogued as rs1211027000, COSV63133386; called by muse, mutect2, varscan2
- MPPE1 | c.291G>A p.Q97= | Silent (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2, varscan2
- PIDD1 | c.1542G>C p.V514= | Silent (SNP) | VAF 33/88 reads (38%) | catalogued as COSV57193691; called by muse, mutect2, varscan2
- TRAJ33 | c.24C>T p.I8= | Silent (SNP) | VAF 7/24 reads (29%) | called by muse, varscan2
- SNORD115-35 | n.52A>C | RNA (SNP) | VAF 11/369 reads (3%) | called by muse, mutect2
